Somatic mutation profile of tumor specimen TCGA-ZJ-A8QR-01A (aliquot TCGA-ZJ-A8QR-01A-11D-A37N-09) from TCGA case TCGA-ZJ-A8QR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 38.9 years (14,225 days).
Specimen TCGA-ZJ-A8QR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fffd6a43-b139-4922-ad27-246c80bcede0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-A8QR-10A (Blood Derived Normal), aliquot TCGA-ZJ-A8QR-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c48cc3-7e2e-4119-9768-e4060941dbc5

The open-access MAF lists 133 somatic variants for this specimen: 103 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 29, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG2 | c.812C>T p.S271F (on ENST00000379869 / NM_001079858.3; = p.S268F on NM_005756.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as rs779017739, COSV100492306; called by muse, mutect2, varscan2
- AIFM1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as COSV99781057; called by muse, mutect2, varscan2
- ANKS3 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV100423102; called by muse, mutect2, varscan2
- AP1M1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs774173547, COSV52224607; called by muse, mutect2, varscan2
- APOB | c.12931G>C p.E4311Q | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99265878; called by muse, mutect2
- ARHGEF26 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1368052860, COSV100726568; called by muse, mutect2, varscan2
- ARMC4 | c.2302C>G p.Q768E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV100536929; called by muse, mutect2, varscan2
- ARMCX2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV57529345; called by muse, mutect2, varscan2
- ASB17 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV52411310, COSV99407957; called by muse, mutect2, varscan2
- ATP11C | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100558025; called by muse, mutect2, varscan2
- BOLL | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV99987112; called by muse, mutect2, varscan2
- BRWD3 | c.4634G>C p.R1545T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as COSV100956124, COSV64751257; called by muse, mutect2, varscan2
- BRWD3 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 74/127 reads (58%) | catalogued as COSV100956125, COSV64751232; called by muse, varscan2
- C11orf58 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV57178549; called by muse, mutect2, varscan2
- CAPN12 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV100185302; called by muse, mutect2, varscan2
- CCDC105 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as rs1489552270, COSV99479928; called by muse, mutect2, varscan2
- CCDC77 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99519909; called by muse, mutect2, varscan2
- CCDC88B | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as rs747595586, COSV100105472; called by muse, mutect2, varscan2
- CDH7 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.142); catalogued as COSV100542483; called by muse, mutect2, varscan2
- CDK17 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344728298, COSV99702785; called by muse, mutect2, varscan2
- CNGB3 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100182091; called by muse, mutect2, varscan2
- CPNE9 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99808299; called by muse, mutect2, varscan2
- CRIM1 | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99753499; called by muse, mutect2, varscan2
- DMD | c.4251G>C p.L1417F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV100819980; called by muse, mutect2, varscan2
- DNAJB14 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV62032997; called by muse, mutect2, varscan2
- DNAJC9 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV54350053; called by muse, mutect2, varscan2
- EME1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99868957; called by muse, mutect2, varscan2
- FAM200A | c.1599G>C p.L533F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.921); catalogued as rs1370948328, COSV101282731; called by muse, mutect2, varscan2
- FAN1 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs745572671, COSV100755993; called by mutect2, varscan2
- FMN2 | c.4522C>G p.R1508G | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145415, COSV60452708; called by muse, mutect2, varscan2
- FRMPD1 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100899571; called by muse, varscan2
- GNAZ | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.398); catalogued as rs1221941233, COSV50738562; called by muse, mutect2, varscan2
- H4C5 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100747935, COSV100747982; called by muse, mutect2, varscan2
- HEATR5A | c.5449G>C p.D1817H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV101120046; called by muse, varscan2
- HLTF | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV100026871; called by muse, mutect2, varscan2
- KIAA1328 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144164188, COSV99694388; called by muse, mutect2, varscan2
- KMT2D | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as rs1385470844, COSV99982497; called by muse, mutect2, varscan2
- KPNA3 | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 19/31 reads (61%) | catalogued as COSV99904148; called by muse, mutect2, varscan2
- LRP1B | c.7877A>G p.N2626S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1024089004, COSV101257699; called by muse, varscan2
- LRRC27 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100689812; called by muse, mutect2, varscan2
- LRRC55 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1227734456, COSV101546745; called by muse, mutect2, varscan2
- MACO1 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV100975190; called by muse, mutect2, varscan2
- MC2R | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as rs769721256, COSV59620712; called by muse, mutect2, varscan2
- MORC2 | c.2128C>T p.P710S (on ENST00000397641 / NM_001303256.3; = p.P648S on NM_014941.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs780648306, COSV53200487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTF1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779682329, COSV65988383; called by muse, mutect2, varscan2
- MTMR10 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100076136; called by muse, mutect2, varscan2
- MYG1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs778692195, COSV99670444; called by muse, mutect2, varscan2
- MYO7A | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.602); catalogued as COSV101289151; called by muse, mutect2, varscan2
- NDUFS8 | c.1-1G>C p.X1_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99141922; called by muse, mutect2, varscan2
- NEDD4L | c.1166C>T p.S389L (on ENST00000400345 / NM_001144967.3; = p.S369L on NM_015277.6) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs776297860, COSV99894994; called by muse, mutect2, varscan2
- NELFA | c.565C>A p.L189M (on ENST00000542778; = p.L178M on NM_005663.5) | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100424889; called by muse, mutect2, varscan2
- NPY1R | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV99648805; called by muse, mutect2, varscan2
- NTNG1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs995369915, COSV99637723, COSV99639652; called by muse, mutect2, varscan2
- NTRK3 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100446684; called by muse, mutect2, varscan2
- OCRL | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100843456; called by muse, mutect2, varscan2
- OLFML2A | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992631; called by muse, mutect2, varscan2
- PATJ | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334371; called by muse, mutect2, varscan2
- PCDHGC5 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191201177, COSV52746883; called by muse, mutect2, varscan2
- PFDN5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV99229384; called by muse, mutect2, varscan2
- PHIP | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99244209; called by muse, mutect2, varscan2
- PHLDB3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1172126324, COSV99415571; called by muse, mutect2, varscan2
- PKDREJ | c.3731C>T p.S1244F | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1393238111, COSV99478968; called by muse, mutect2, varscan2
- PLXNB2 | c.2182-2A>C p.X728_splice | Splice Site (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100834087; called by muse, mutect2, varscan2
- PRCD | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs771143178, COSV99506142; called by muse, mutect2, varscan2
- RAB3GAP2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99424752; called by muse, mutect2, varscan2
- RFX7 | c.2326G>A p.E776K (on ENST00000559447 / NM_001368074.1; = p.E873K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.104); catalogued as COSV100428046, COSV57970033; called by muse, mutect2, varscan2
- RGL2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV101004788; called by muse, mutect2, varscan2
- RGS22 | c.1455G>A p.W485* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV62657562; called by muse, varscan2
- RGS22 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100693305; called by muse, varscan2
- RGS4 | c.228C>G p.F76L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100905578, COSV63357276; called by muse, mutect2, varscan2
- RNF165 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99491720; called by muse, mutect2, varscan2
- RPS25 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs782183167, COSV100548777; called by muse, varscan2
- SEMA4D | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358420, COSV59396879; called by muse, mutect2, varscan2
- SENP7 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100053293; called by muse, mutect2, varscan2
- SHF | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as COSV99334504; called by muse, mutect2, varscan2
- SLC8A3 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.062); catalogued as COSV100776224, COSV100776283; called by muse, mutect2
- SLC9A2 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201828131, COSV52137779; called by muse, mutect2, varscan2
- SMG7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100750338; called by muse, mutect2, varscan2
- SMURF1 | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100742475; called by muse, mutect2, varscan2
- SRBD1 | c.2488C>G p.P830A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55402848, COSV99765096; called by muse, mutect2, varscan2
- SUGP1 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as rs749160884, COSV99895142; called by muse, mutect2, varscan2
- SYPL1 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.901); catalogued as rs778412371, COSV99163434, COSV99163448; called by muse, mutect2, varscan2
- TENM1 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100950168; called by muse, mutect2, varscan2
- TESPA1 | c.1316G>A p.R439K (on ENST00000316577 / NM_001098815.3; = p.R301K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100345286; called by muse, mutect2, varscan2
- TEX47 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99787299; called by muse, mutect2
- THADA | c.5089G>C p.E1697Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs765010895, COSV100368732; called by muse, mutect2, varscan2
- TICRR | c.3406G>C p.E1136Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as COSV99176556; called by muse, mutect2
- TMED2 | c.253C>G p.H85D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99147846; called by muse, mutect2, varscan2
- TOMM70 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV99424371; called by muse, mutect2, varscan2
- TSKU | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.237); catalogued as COSV100290106; called by muse, mutect2
- UEVLD | c.1022A>G p.K341R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV100293208; called by muse, varscan2
- USP9X | c.7626G>A p.M2542I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100199378, COSV61068424; called by muse, mutect2, varscan2
- UTP14A | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100928965; called by muse, mutect2, varscan2
- VPS13D | c.8125G>A p.E2709K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV99166863; called by muse, mutect2, varscan2
- ZIM3 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54145062; called by muse, mutect2, varscan2
- ZNF160 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100762347; called by muse, mutect2, varscan2
- ZNF208 | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV101237040; called by muse, mutect2, varscan2
- ZNF286A | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV101224798; called by muse, mutect2
- ZNF488 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs781822035; called by muse, mutect2, varscan2
- ZNF786 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1466820637, COSV100302866; called by muse, mutect2, varscan2
- ABCA5 | c.4421C>T p.A1474V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.2); called by muse, mutect2
- AHNAK2 | c.9627del p.K3210Sfs*30 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by pindel, varscan2
- CDKN1A | c.250_268del p.R84Efs*58 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ADGRG7 | c.1257T>C p.A419= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV56299091; called by muse, mutect2, varscan2
- ANAPC4 | c.1833G>C p.V611= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs886088265, COSV100194075; called by muse, mutect2, varscan2
- BCL9L | c.3084C>G p.L1028= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99419373; called by muse, mutect2, varscan2
- CFAP58 | c.81C>G p.L27= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1208560470, COSV100458954; called by muse, mutect2
- DMXL1 | c.6111C>T p.L2037= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100224093; called by muse, mutect2, varscan2
- DNAAF2 | c.1878C>T p.V626= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100024115; called by muse, mutect2, varscan2
- DNAH7 | c.11658C>T p.T3886= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs555417845, COSV56770478; called by muse, mutect2, varscan2
- FBXL12 | c.480C>T p.R160= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs973637574, COSV99928021; called by muse, mutect2, varscan2
- FLAD1 | c.270G>A p.Q90= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99422012, COSV99422559; called by muse, mutect2, varscan2
- GPX4 | c.456G>A p.K152= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs755415132, COSV100684595; called by muse, mutect2, varscan2
- HEPH | c.210G>C p.G70= (on ENST00000343002; = p.G124= on NM_138737.5) | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100294937; called by muse, mutect2, varscan2
- IGLV8-61 | c.219C>T p.L73= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV101135133; called by muse, mutect2, varscan2
- MAPK1 | c.213G>A p.E71= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99308009; called by muse, mutect2, varscan2
- NPFFR1 | c.1292G>A p.*431= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99524835; called by muse, mutect2, varscan2
- NR0B1 | c.297G>A p.A99= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100973536, COSV66763951; called by muse, mutect2
- NRCAM | c.756G>A p.L252= (on ENST00000379028 / NM_001371124.1; = p.L246= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100694516, COSV61030423; called by muse, mutect2, varscan2
- P2RY8 | c.618C>T p.F206= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1375126755, COSV67177366; called by muse, mutect2, varscan2
- PCDH11X | c.2136T>C p.R712= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100012076; called by muse, mutect2
- POLR1A | c.828G>A p.L276= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99807765; called by muse, mutect2, varscan2
- POU4F1 | c.825C>T p.F275= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV101020558; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1290G>A p.L430= (on ENST00000352766; = p.L351= on NM_181334.5) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1181646352, COSV100424312, COSV61233755; called by muse, mutect2, varscan2
- RNF165 | c.963G>A p.V321= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1428292860, COSV99491721; called by muse, mutect2, varscan2
- SOX14 | c.357G>A p.L119= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100048222; called by muse, mutect2, varscan2
- SYNE2 | c.4350C>T p.I1450= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100647789, COSV59958646; called by muse, mutect2, varscan2
- TENM1 | c.870C>A p.P290= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100950167; called by muse, mutect2, varscan2
- TFDP3 | c.684C>T p.F228= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1167773019, COSV100033400; called by mutect2, varscan2
- TRAK1 | c.210C>T p.L70= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100565645; called by muse, mutect2, varscan2
- TTN | c.20055C>T p.I6685= (on ENST00000591111; = p.I5758= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100615607, COSV59958545; called by muse, mutect2, varscan2
- ZNF607 | c.792C>G p.L264= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV67697206; called by muse, mutect2, varscan2
- KNOP1P1 | n.407G>A | RNA (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
